Somatic mutation profile of tumor specimen ASCProject_0055_T2_WES (aliquot ASCProject_0055_T2_WES_1) from CMI case ASCProject_0055, project CMI-ASC: Count Me In (CMI): The Angiosarcoma (ASC) Project. Sex at birth: female; Primary diagnosis: Angiosarcoma; Tissue or organ of origin: Breast, NOS; Age at diagnosis: 37.8 years (13,822 days).
Specimen ASCProject_0055_T2_WES: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Biospecimen anatomic site: Muscle; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 94a74600-95b7-4ffe-b7e5-292d0e22f0e2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ASCProject_0055_SALIVA (Saliva), aliquot ASCProject_0055_SALIVA_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/57b4b00d-f688-4b2a-aae7-f4d40186de26

The open-access MAF lists 41 somatic variants for this specimen: 29 protein-altering or splice-affecting, 6 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 21, Silent 6, Intron 3, Splice Site 3, Splice Region 2, Nonsense Mutation 2, RNA 1, Frame Shift Del 1, 3'UTR 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.746G>C p.R249T | Missense Mutation (SNP) | VAF 26/247 reads (11%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs587782329, COSV52666526, COSV52668050, COSV52697169, COSV52713804; ClinVar: not provided / likely pathogenic; called by muse, mutect2, varscan2
- BARHL2 | c.529G>T p.A177S | Missense Mutation (SNP) | VAF 30/517 reads (6%) | SIFT tolerated (0.31); PolyPhen benign (0.072); catalogued as rs764468861, COSV100966082; called by muse, mutect2
- CPNE7 | c.1516G>A p.G506R | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT tolerated (0.36); PolyPhen benign (0.024); catalogued as rs763159653, COSV52014453; called by mutect2, varscan2
- DCAF12L1 | c.1169C>G p.T390S | Missense Mutation (SNP) | VAF 8/69 reads (12%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV64422984; called by muse, mutect2, varscan2
- KRTAP19-7 | c.31C>A p.L11I | Missense Mutation (SNP) | VAF 15/149 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.399); catalogued as rs1192725528; called by muse, mutect2
- MTRR | c.148T>C p.C50R (on ENST00000264668; = p.C23R on NM_002454.3 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 42/718 reads (6%) | SIFT tolerated (0.42); PolyPhen benign (0.122); catalogued as rs781726691; called by muse, mutect2
- NF1 | c.6704+1G>C p.X2235_splice (on ENST00000358273 / NM_001042492.3; = p.X2214_splice on NM_000267.3) | Splice Site (SNP) | VAF 32/299 reads (11%) | catalogued as rs1060500376, CD040919, CS041539, CS137212, CS982281, COSV62197389, COSV62217889, COSV62218380; called by muse, mutect2, varscan2
- PSG6 | c.287G>A p.G96E | Missense Mutation (SNP) | VAF 23/199 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.153); catalogued as rs529836601; called by muse, mutect2, varscan2
- SULT1C2 | c.323C>T p.T108I | Missense Mutation (SNP) | VAF 13/156 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.806); catalogued as COSV99264927; called by muse, mutect2
- ARAP1 | c.1992+8C>T | Splice Region (SNP) | VAF 15/210 reads (7%) | called by muse, mutect2
- BMPER | c.319+1G>A p.X107_splice | Splice Site (SNP) | VAF 61/420 reads (15%) | called by muse, mutect2, varscan2
- CCDC18 | c.3133A>G p.I1045V (on ENST00000343253 / NM_001306076.1; = p.I1046V on NM_206886.4) | Missense Mutation (SNP) | VAF 12/115 reads (10%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.741); called by muse, mutect2, varscan2
- CEP85L | c.424G>T p.D142Y | Missense Mutation (SNP) | VAF 11/228 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); called by muse, mutect2
- DNAH5 | c.9849del p.K3283Nfs*9 | Frame Shift Del (DEL) | VAF 48/480 reads (10%) | called by mutect2, varscan2
- EVC2 | c.2701C>A p.L901M | Missense Mutation (SNP) | VAF 30/418 reads (7%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.809); called by muse, mutect2
- GPC6 | c.550G>T p.E184* | Nonsense Mutation (SNP) | VAF 23/278 reads (8%) | called by muse, mutect2
- GPR179 | c.1894-1G>A p.X632_splice (on ENST00000621958; = p.X631_splice on NM_001004334.4) | Splice Site (SNP) | VAF 3/36 reads (8%) | called by muse, mutect2
- GRIN2A | c.1007+8A>T | Splice Region (SNP) | VAF 28/252 reads (11%) | called by muse, mutect2, varscan2
- HTR1F | c.302G>C p.S101T | Missense Mutation (SNP) | VAF 6/112 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.959); called by muse, mutect2
- LRP1B | c.8762A>G p.D2921G | Missense Mutation (SNP) | VAF 12/280 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.72); called by muse, mutect2
- MAGEE1 | c.1600A>T p.R534W | Missense Mutation (SNP) | VAF 14/194 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- MKI67 | c.3338G>T p.G1113V | Missense Mutation (SNP) | VAF 28/292 reads (10%) | SIFT tolerated (0.3); PolyPhen benign (0.1); called by muse, mutect2
- NLGN4X | c.1216C>T p.L406F | Missense Mutation (SNP) | VAF 18/270 reads (7%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.462); called by muse, mutect2, varscan2
- PXDN | c.2339G>A p.G780D | Missense Mutation (SNP) | VAF 14/426 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- RGS7 | c.679C>T p.R227W | Missense Mutation (SNP) | VAF 44/319 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.696); called by muse, mutect2, varscan2
- RIC8A | c.448C>A p.L150M | Missense Mutation (SNP) | VAF 13/239 reads (5%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.98); called by muse, mutect2
- TAS1R2 | c.473T>G p.L158R | Missense Mutation (SNP) | VAF 3/38 reads (8%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.678); called by muse, mutect2
- TMEM215 | c.578A>C p.E193A | Missense Mutation (SNP) | VAF 24/270 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.981); called by muse, mutect2
- ZNF224 | c.115G>T p.E39* | Nonsense Mutation (SNP) | VAF 10/127 reads (8%) | called by muse, mutect2
- AKAP12 | c.4143C>T p.P1381= | Silent (SNP) | VAF 29/238 reads (12%) | called by muse, mutect2, varscan2
- CLP1 | c.1131C>T p.N377= | Silent (SNP) | VAF 28/328 reads (9%) | called by muse, mutect2
- DNAH11 | c.4179C>T p.S1393= | Silent (SNP) | VAF 10/154 reads (6%) | catalogued as rs1403365658; called by muse, mutect2
- ORC3 | c.1548A>G p.S516= | Silent (SNP) | VAF 18/223 reads (8%) | catalogued as COSV57641047; called by muse, mutect2
- SVOPL | c.396G>A p.S132= | Silent (SNP) | VAF 27/291 reads (9%) | catalogued as rs538349256; called by muse, mutect2, varscan2
- TCF23 | c.360C>T p.L120= | Silent (SNP) | VAF 29/215 reads (13%) | catalogued as rs370405355; called by muse, mutect2, varscan2
- AC116655.1 | n.19G>T | RNA (SNP) | VAF 10/335 reads (3%) | called by muse, mutect2
- ADAM9 | c.*1160A>G | 3'UTR (SNP) | VAF 33/118 reads (28%) | catalogued as rs541304766; called by muse, mutect2, varscan2
- C2CD6 | c.1581+2243A>T | Intron (SNP) | VAF 10/73 reads (14%) | called by muse, mutect2, varscan2
- CAMKMT | c.377-72780T>A | Intron (SNP) | VAF 16/236 reads (7%) | called by muse, mutect2
- SLC4A2 | c.51+573C>T | Intron (SNP) | VAF 4/44 reads (9%) | catalogued as rs1181829938; called by muse, mutect2
- VPS11 | c.-165A>G | 5'UTR (SNP) | VAF 14/150 reads (9%) | called by muse, mutect2
